Somatic mutation profile of tumor specimen TCGA-WB-A81E-01A (aliquot TCGA-WB-A81E-01A-11D-A35I-08) from TCGA case TCGA-WB-A81E, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 47.7 years (17,407 days).
Specimen TCGA-WB-A81E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 919f1343-8f0e-4229-984b-ef5d6e4bcefc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81E-10A (Blood Derived Normal), aliquot TCGA-WB-A81E-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/887acdb3-6dc5-4374-a0bb-b5fc1e029f7b

The open-access MAF lists 17 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 14, Splice Region 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSTF1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53860662; called by muse, mutect2
- GGT7 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs1385647005, COSV60542771; called by muse, mutect2, varscan2
- GIGYF2 | c.3845A>G p.N1282S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs759895571, COSV65251770; called by muse, mutect2, varscan2
- HDAC2 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV64037804; called by muse, mutect2
- ITGAV | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as rs572317414; called by muse, mutect2, varscan2
- LGALS14 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs111361406, COSV62372178; called by muse, mutect2
- LSS | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as COSV62701221; called by muse, mutect2
- TOX | c.1545G>A p.G515= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100813061, COSV63845227; called by muse, mutect2, varscan2
- C10orf90 | c.1898A>G p.D633G | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CGNL1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2
- DMBT1 | c.6441C>A p.D2147E (on ENST00000338354 / NM_001377530.1; = p.D1390E on NM_004406.3) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.131); called by muse, varscan2
- EIF3K | c.626-2A>C p.X209_splice | Splice Site (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- GAD1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MORC3 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- PFKM | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUPT6H | c.3997C>T p.P1333S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDKL5 | c.972T>C p.S324= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
